Somatic mutation profile of tumor specimen 0DB2BA from CCDI case PBBJJS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 18.2 years (6,638 days).
Specimen 0DB2BA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2415515d-436b-4ee5-884d-22b5f355fd0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DB2AP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01c125da-0f0c-41d1-93d9-ca4f44f5d501

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.331A>G p.S111G | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs1559426203, CD951874, CM023997, CM1510662, COSV56547849, COSV56551476, COSV56558946; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- NDUFA6 | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 125/860 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1344786479; called by muse, varscan2
- PIEZO2 | c.7015C>T p.R2339C | Missense Mutation (SNP) | VAF 98/817 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775464447, COSV53287135; called by muse, varscan2
- UGT2B11 | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 112/972 reads (12%) | catalogued as COSV101485244; called by muse, varscan2
- MYO18A | c.5127G>A p.M1709I | Missense Mutation (SNP) | VAF 72/572 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.191); called by muse, varscan2
- ZFHX2 | c.6113T>C p.L2038P | Missense Mutation (SNP) | VAF 42/194 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); called by muse, varscan2
- MAST1 | c.1566G>A p.G522= | Silent (SNP) | VAF 64/504 reads (13%) | catalogued as COSV52256375; called by muse, varscan2
- SLC20A1 | c.252C>A p.T84= | Silent (SNP) | VAF 98/702 reads (14%) | called by muse, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 37/327 reads (11%) | called by muse, varscan2
